Gene-level copy-number profile of tumor specimen TCGA-AA-3561-01A from TCGA case TCGA-AA-3561, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.3 years (26,420 days).
Specimen TCGA-AA-3561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6eebf1e5-e148-4c15-804f-08b6b2d95b66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3561-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5073f565-387b-4e9f-a97b-95743f0b4ef7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,352; copy number 3: 3,336; copy number 4: 42,700; copy number 5: 40; copy number 6: 2,826; copy number 7: 1,517; copy number 9: 1,009; copy number 10: 755; copy number 11: 210; copy number 12: 14; copy number 18: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3561-01A-01D-0819-01): tumor purity 0.82, ploidy 4.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,044 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:36,740,775–36,839,444, 1 gene, copy number 18 (within-gene range 3–18): CPNE5.
- chr6:36,841,430–49,636,839, 279 genes, copy number 11–18 (broad region; genes not listed).
- chr13:18,467,172–59,480,132, 755 genes, copy number 9 (broad region; genes not listed).
- chr13:71,845,981–114,337,626, 544 genes, copy number 10 (broad region; genes not listed).
- chr20:31,257,664–36,863,538, 211 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr20:56,295,967–64,313,132, 254 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
